Somatic mutation profile of tumor specimen C3L-01840-02 (aliquot CPT0091990009) from CPTAC case C3L-01840, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.2 years (20,522 days).
Specimen C3L-01840-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e68b02bd-230a-4ac0-904b-35ec920bea50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01840-31 (Blood Derived Normal), aliquot CPT0093700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/935f3551-91ec-4d31-88c1-11d961705365

The open-access MAF lists 62 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Intron 7, Nonsense Mutation 3, In Frame Del 2, 5'UTR 2, RNA 2, Frame Shift Del 1, Splice Site 1, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 191/523 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 57/148 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.757dup p.I253Nfs*45 | Frame Shift Ins (INS) | VAF 158/445 reads (36%) | catalogued as rs1114167661, CI115964, COSV64295619, COSV64295627; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 196/472 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1554826024, CM115950, COSV64298403, COSV64309667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COG7 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs767025710; called by muse, mutect2, varscan2
- DCAF12L1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 158/411 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV64421672; called by muse, mutect2, varscan2
- DKK4 | c.74_76del p.N25del | In Frame Del (DEL) | VAF 76/203 reads (37%) | catalogued as rs780368591; called by pindel, varscan2
- FAM161B | c.1466C>T p.S489F (on ENST00000651776; = p.S426F on NM_152445.3) | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as rs757258224; called by muse, mutect2, varscan2
- FAM50B | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66654701; called by muse, mutect2, varscan2
- GDPD4 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs532591376; called by muse, mutect2, varscan2
- GFRA1 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770678431; called by muse, mutect2, varscan2
- KCNV1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52084480, COSV52086450; called by muse, mutect2, varscan2
- KRT72 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs773510817, COSV53376670; called by muse, mutect2, varscan2
- LRCH4 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752664210; called by muse, mutect2, varscan2
- LRRC7 | c.1518_1520del p.E506del (on ENST00000651989 / NM_001370785.2; = p.E473del on NM_001330635.3 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 52/160 reads (33%) | catalogued as rs1450766734; called by pindel, varscan2
- MUC12 | c.13063G>A p.V4355I (on ENST00000379442; = p.V4212I on NM_001164462.1) | Missense Mutation (SNP) | VAF 85/713 reads (12%) | SIFT tolerated (0.24); catalogued as rs199664042; called by muse, mutect2, varscan2
- NRXN2 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763745028; called by muse, mutect2
- OR1C1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1439149981, COSV68715697; called by muse, mutect2, varscan2
- OR2B11 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 156/474 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs764642577, COSV59509708; called by muse, mutect2, varscan2
- OR6K2 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 152/430 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs150711789, COSV62743285, COSV62743462; called by muse, mutect2, varscan2
- ORC1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 174/423 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1026941164, COSV65365023; called by muse, mutect2, varscan2
- SIM1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1398673847; called by muse, mutect2, varscan2
- SLIT1 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs777148896, COSV56600292; called by muse, mutect2, varscan2
- SNX14 | c.1678C>T p.R560* (on ENST00000314673 / NM_001350535.1; = p.R507* on NM_020468.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 136/366 reads (37%) | catalogued as rs1405366930, COSV59017610; called by muse, mutect2, varscan2
- SVEP1 | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs781746377, COSV100239476; called by muse, mutect2, varscan2
- TMEM132E | c.2159G>A p.R720Q (on ENST00000321639; = p.R810Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs374583943, COSV58694836; called by muse, mutect2, varscan2
- ZNF574 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | PolyPhen benign (0.157); catalogued as rs1012859362; called by muse, mutect2, varscan2
- APLP1 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ARID1A | c.1827del p.S610Lfs*9 | Frame Shift Del (DEL) | VAF 80/211 reads (38%) | called by mutect2, pindel, varscan2
- BRWD3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 173/407 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CTCF | c.1714A>T p.R572* | Nonsense Mutation (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- EIF3D | c.309G>A p.R103= | Splice Region (SNP) | VAF 108/252 reads (43%) | called by muse, varscan2
- FOXRED1 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 268/618 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KIF1C | c.2417C>T p.T806I | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYC | c.167_169dup p.L56dup (on ENST00000377970; = p.L71dup on NM_002467.6) | In Frame Ins (INS) | VAF 26/62 reads (42%) | called by mutect2, varscan2
- NPTXR | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 103/227 reads (45%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- RAB6C | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- SARS1 | c.1100-8_1100delinsTTTTTTTTT p.X367_splice | Splice Site (ONP) | VAF 4/50 reads (8%) | called by mutect2*, pindel
- SCML2 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, varscan2
- SETDB1 | c.3205A>G p.K1069E | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- ZNF536 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABLIM3 | c.1320C>T p.I440= | Silent (SNP) | VAF 114/265 reads (43%) | called by muse, mutect2, varscan2
- CYB561A3 | c.468C>T p.H156= | Silent (SNP) | VAF 92/213 reads (43%) | catalogued as rs377472853; called by muse, mutect2, varscan2
- KIAA2026 | c.5391G>T p.V1797= | Silent (SNP) | VAF 82/208 reads (39%) | catalogued as rs1269851911; called by muse, mutect2, varscan2
- KRT31 | c.399C>T p.N133= | Silent (SNP) | VAF 111/252 reads (44%) | catalogued as rs538647973, COSV52435279, COSV99289372; called by muse, mutect2, varscan2
- NAT8L | c.744G>A p.T248= | Silent (SNP) | VAF 78/154 reads (51%) | catalogued as rs751707718; called by muse, mutect2, varscan2
- OLFML2B | c.1737C>T p.R579= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs142854687, COSV54194361; called by muse, mutect2, varscan2
- OR10A5 | c.81G>A p.L27= | Silent (SNP) | VAF 162/393 reads (41%) | catalogued as rs769810350; called by muse, mutect2, varscan2
- PCDHB9 | c.1635G>A p.A545= | Silent (SNP) | VAF 308/747 reads (41%) | catalogued as rs1417941624, COSV53380765; called by muse, mutect2, varscan2
- STAT5B | c.1104G>A p.Q368= | Silent (SNP) | VAF 118/347 reads (34%) | called by mutect2, varscan2
- ARMCX4 | c.1038+2635G>A | Intron (SNP) | VAF 68/159 reads (43%) | called by muse, mutect2, varscan2
- ASH1L | c.-412_-387del | 5'UTR (DEL) | VAF 79/398 reads (20%) | catalogued as rs1450945000; called by mutect2, pindel, varscan2
- C2CD6 | c.1582-3431C>T | Intron (SNP) | VAF 123/285 reads (43%) | called by muse, mutect2, varscan2
- C8orf82 | c.156+324A>G | Intron (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- ELOVL5 | c.246+3887G>A | Intron (SNP) | VAF 130/300 reads (43%) | catalogued as rs759512383; called by muse, mutect2, varscan2
- ICOS | c.-29G>A | 5'UTR (SNP) | VAF 155/361 reads (43%) | catalogued as rs1246974238, COSV100320323; called by muse, mutect2, varscan2
- MIR124-2HG | n.336G>A | RNA (SNP) | VAF 97/215 reads (45%) | called by muse, mutect2, varscan2
- MRRFP1 | n.330A>G | RNA (SNP) | VAF 137/340 reads (40%) | catalogued as rs1183128380; called by muse, mutect2, varscan2
- PRMT8 | c.418-914C>T | Intron (SNP) | VAF 53/153 reads (35%) | catalogued as rs778629778; called by muse, mutect2, varscan2
- PSG1 | c.1243+20G>A | Intron (SNP) | VAF 100/236 reads (42%) | catalogued as rs369963338, COSV99741603; called by muse, mutect2, varscan2
- TYK2 | c.2466+164G>T | Intron (SNP) | VAF 155/368 reads (42%) | called by muse, mutect2, varscan2
